Gene-level copy-number profile of tumor specimen TCGA-2G-AAGU-01A from TCGA case TCGA-2G-AAGU, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 40.2 years (14,692 days).
Specimen TCGA-2G-AAGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6fdab3f7-536f-4a0f-89e9-85d1afc03042.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAGU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/d3a3f2fc-25f1-479d-b61d-7bd03018bb92

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 514; copy number 2: 4,954; copy number 3: 21,953; copy number 4: 14,966; copy number 5: 11,168; copy number 6: 3,771; copy number 7: 669; copy number 8: 66; copy number 9: 94; copy number 10: 737.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–46,870, 1 gene: FAM110C.
- chr10:87,201,647–87,357,882, 5 genes (within-gene range 0–3): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863.
- chr18:45,034–73,545, 3 genes: AP001005.1, TUBB8B, AP001005.3.
- chr21:8,603,547–8,603,984, 1 gene: RPSAP68.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,566 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:130,048,143–130,055,920, 1 gene, copy number 7: AC083906.4.
- chr8:46,028,804–56,218,809, 151 genes, copy number 7 (broad region; genes not listed).
- chr8:78,268,637–85,449,040, 109 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr9:60,914,407–61,642,494, 15 genes, copy number 7: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA.
- chr12:66,767–34,249,958, 831 genes, copy number 9–10 (broad region; genes not listed).
- chr14:18,333,726–24,419,283, 459 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
